Somatic mutation profile of tumor specimen C3L-06206-04 (aliquot CPT0424700006) from CPTAC case C3L-06206, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.8 years (26,220 days).
Specimen C3L-06206-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ced3b5d9-436e-416e-9951-5f9b8d41aceb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06206-32 (Blood Derived Normal), aliquot CPT0424820003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/68ef1246-6603-4676-bdae-5c59ee9bee8c

The open-access MAF lists 5,116 somatic variants for this specimen: 3,241 protein-altering or splice-affecting, 1,682 silent, 193 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,983, Silent 1,682, Nonsense Mutation 175, Intron 113, Splice Region 45, 5'Flank 24, 3'UTR 19, Splice Site 18, RNA 14, 5'UTR 12, 3'Flank 11, Frame Shift Del 10.

Variants (750 of 5,116; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 526/669 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.*1682C>T | 3'UTR (SNP) | VAF 108/275 reads (39%) | catalogued as rs863225163, COSV57054074; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DES | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 95/297 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as rs62635763, CM072982, COSV100900438; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNAH5 | c.8030G>A p.R2677Q | Missense Mutation (SNP) | VAF 77/134 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886043448, CM1310742, COSV54226107; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- EPB41L4A | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 105/275 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs730882207, CM150853, COSV54862790; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNB1 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 176/479 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555889130, CM1511116, COSV65569863; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 129/342 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.3470G>A p.R1157Q | Missense Mutation (SNP) | VAF 132/434 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60786347; called by muse, mutect2, varscan2
- A1CF | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 107/287 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1178467016; called by muse, mutect2, varscan2
- AATK | c.2287C>T p.P763S (on ENST00000326724 / NM_001080395.3; = p.P660S on NM_004920.2) | Missense Mutation (SNP) | VAF 203/686 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs968733057; called by muse, mutect2, varscan2
- ABCA13 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 104/486 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.029); catalogued as rs1414676748; called by muse, mutect2, varscan2
- ABCA4 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs548888187, COSV64672582; called by muse, mutect2, varscan2
- ABCA9 | c.2278C>T p.P760S | Missense Mutation (SNP) | VAF 113/217 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); catalogued as rs752536538, COSV60630834; called by muse, mutect2, varscan2
- ABCB1 | c.3046C>T p.P1016S | Missense Mutation (SNP) | VAF 212/406 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55952008; called by muse, mutect2, varscan2
- ABCC1 | c.3969C>T p.V1323= | Splice Region (SNP) | VAF 94/282 reads (33%) | catalogued as rs759266398, COSV60695684; called by muse, mutect2, varscan2
- ABCC4 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs267603866, COSV100972205; called by muse, mutect2, varscan2
- ABCC6 | c.3178C>T p.P1060S | Missense Mutation (SNP) | VAF 226/620 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1447101816; called by muse, mutect2, varscan2
- ABCC9 | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53961664; called by muse, mutect2, varscan2
- ABCD1 | c.1949C>T p.A650V | Missense Mutation (SNP) | VAF 120/334 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.043); catalogued as rs1557055333, CD961757; ClinVar: likely benign; called by muse, varscan2
- ABCG8 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 73/254 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs762542767, COSV55390931; called by muse, mutect2, varscan2
- ABLIM1 | c.1338G>A p.M446I | Missense Mutation (SNP) | VAF 136/351 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1324163827; called by muse, mutect2, varscan2
- AC244197.3 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 175/463 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM950670; called by muse, mutect2, varscan2
- ACAN | c.6049G>A p.E2017K | Missense Mutation (SNP) | VAF 135/387 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); catalogued as COSV100719421, COSV61368457; called by muse, mutect2, varscan2
- ACIN1 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1392029658; called by mutect2, varscan2
- ACSL6 | c.378G>A p.V126= (on ENST00000379240; = p.V151= on NM_015256.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 72/241 reads (30%) | catalogued as COSV57304925; called by muse, mutect2, varscan2
- ACSM1 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778016594; called by muse, mutect2, varscan2
- ACSM1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 90/292 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV54634765; called by muse, mutect2, varscan2
- ACSS3 | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 170/442 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1317149853; called by muse, varscan2
- ACTN4 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53146756; called by muse, mutect2, varscan2
- ACTN4 | c.2507C>T p.S836L | Missense Mutation (SNP) | VAF 148/461 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs766882748, COSV53151095; called by muse, mutect2, varscan2
- ACTRT1 | c.748C>A p.H250N | Missense Mutation (SNP) | VAF 192/488 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV64420051; called by muse, varscan2
- ADAD1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56646823; called by muse, mutect2, varscan2
- ADAM18 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 93/278 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs267601916, COSV55844457; called by muse, mutect2, varscan2
- ADAM18 | c.1852C>T p.H618Y | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.296); catalogued as rs866076661, COSV55845988; called by muse, mutect2, varscan2
- ADAM21 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 134/362 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs375714568, COSV50791466; called by muse, mutect2, varscan2
- ADAM22 | c.2122G>A p.G708S | Missense Mutation (SNP) | VAF 77/357 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373708797; called by muse, mutect2, varscan2
- ADAM29 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 90/239 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs969112783, COSV63660495; called by muse, mutect2, varscan2
- ADAM30 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 130/346 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1280658470, COSV101023966; called by muse, mutect2, varscan2
- ADAMDEC1 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV56475287; called by muse, mutect2, varscan2
- ADAMTS12 | c.4210C>T p.H1404Y | Missense Mutation (SNP) | VAF 158/433 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV61260013, COSV61263402; called by muse, mutect2, varscan2
- ADAMTS17 | c.2813G>A p.G938D | Missense Mutation (SNP) | VAF 105/289 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751171691; called by muse, mutect2, varscan2
- ADAMTS19 | c.958G>A p.G320R | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.025); catalogued as COSV50767886; called by muse, mutect2, varscan2
- ADAMTS19 | c.2096G>A p.R699K | Missense Mutation (SNP) | VAF 115/364 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50732906, COSV99176182; called by muse, mutect2, varscan2
- ADAMTS20 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 82/279 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs1005720002, COSV67135895; called by muse, mutect2, varscan2
- ADAMTS4 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 682/921 reads (74%) | SIFT tolerated (0.3); PolyPhen benign (0.109); catalogued as rs1482703181; called by muse, mutect2, varscan2
- ADAMTS6 | c.3307C>T p.R1103* | Nonsense Mutation (SNP) | VAF 134/350 reads (38%) | catalogued as rs771517412; called by muse, mutect2, varscan2
- ADAMTS6 | c.2093G>A p.G698E | Missense Mutation (SNP) | VAF 92/275 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV66856785; called by muse, varscan2
- ADAMTS8 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 124/205 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs751058114; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3586C>A p.L1196M | Missense Mutation (SNP) | VAF 324/425 reads (76%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.961); catalogued as rs752827263; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4691G>A p.G1564D | Missense Mutation (SNP) | VAF 302/389 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200593369; called by muse, mutect2, varscan2
- ADAMTSL3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 134/367 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54455990; called by muse, mutect2, varscan2
- ADCY10 | c.3776C>T p.S1259L | Missense Mutation (SNP) | VAF 107/311 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1413593691, COSV63238340; called by muse, mutect2, varscan2
- ADCY4 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 186/500 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV60256164; called by muse, mutect2, varscan2
- ADCY5 | c.178dup p.A60Gfs*27 | Frame Shift Ins (INS) | VAF 182/471 reads (39%) | catalogued as rs756172692; called by mutect2, varscan2
- ADCY7 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 142/384 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.119); catalogued as COSV54269702; called by muse, mutect2, varscan2
- ADD2 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 145/402 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.351); catalogued as rs782005723, COSV100034336; called by muse, mutect2, varscan2
- ADGRA1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 86/203 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as rs1361791050, COSV66931233; called by muse, mutect2, varscan2
- ADGRB3 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 113/474 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1363049892, COSV65419101; called by muse, mutect2, varscan2
- ADGRD1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 101/278 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.99); catalogued as COSV99895320; called by muse, mutect2, varscan2
- ADGRE1 | c.2239G>A p.E747K | Missense Mutation (SNP) | VAF 113/297 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs763519732, COSV51679175; called by muse, mutect2, varscan2
- ADGRF4 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 129/359 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs372713361; called by muse, mutect2, varscan2
- ADGRG2 | c.256G>A p.E86K (on ENST00000379869 / NM_001079858.3; = p.E83K on NM_005756.4) | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756209879; called by muse, varscan2
- ADGRG4 | c.5303C>T p.S1768F | Missense Mutation (SNP) | VAF 164/436 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV54959950; called by muse, mutect2, varscan2
- ADGRL2 | c.3786G>A p.M1262I (on ENST00000370717 / NM_001366005.1; = p.M1206I on NM_012302.4) | Missense Mutation (SNP) | VAF 114/335 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs866681517, COSV54686571; called by muse, mutect2, varscan2
- ADGRL3 | c.530C>T p.P177L (on ENST00000506720 / NM_001322402.2; = p.P109L on NM_015236.6) | Missense Mutation (SNP) | VAF 126/297 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766951668, COSV101547446, COSV72267536; called by muse, mutect2, varscan2
- ADGRV1 | c.2824C>T p.P942S | Missense Mutation (SNP) | VAF 124/361 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67993212; called by muse, mutect2, varscan2
- ADGRV1 | c.3478G>A p.D1160N | Missense Mutation (SNP) | VAF 139/418 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1050411361, COSV67989233, COSV67993711; called by muse, mutect2, varscan2
- ADGRV1 | c.11116G>A p.G3706R | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs771220294; called by muse, mutect2, varscan2
- ADGRV1 | c.11798C>T p.P3933L | Missense Mutation (SNP) | VAF 142/382 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1160448959, COSV67986342; called by muse, mutect2, varscan2
- ADGRV1 | c.12161C>T p.S4054L | Missense Mutation (SNP) | VAF 124/354 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV101316244; called by muse, mutect2, varscan2
- AFF2 | c.2372C>T p.P791L | Missense Mutation (SNP) | VAF 180/524 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV54000426; called by muse, mutect2, varscan2
- AGAP6 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 179/484 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs148430930, COSV65017376; called by muse, mutect2, varscan2
- AGBL1 | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 154/435 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV66870300; called by muse, mutect2, varscan2
- AGBL1 | c.1987G>A p.G663R | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1207016911; called by muse, mutect2, varscan2
- AGBL5 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 85/249 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754757439; called by muse, mutect2, varscan2
- AGO4 | c.1859C>T p.T620I | Missense Mutation (SNP) | VAF 188/495 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as COSV64616666; called by muse, mutect2, varscan2
- AGTPBP1 | c.1570C>T p.H524Y (on ENST00000357081 / NM_001330701.2; = p.H484Y on NM_015239.2) | Missense Mutation (SNP) | VAF 117/363 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771648309; called by muse, mutect2, varscan2
- AGTR2 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 209/552 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100903642; called by muse, varscan2
- AHNAK2 | c.6077C>T p.S2026F | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV60928942; called by muse, mutect2
- AHNAK2 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 214/555 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs371792227; called by muse, mutect2, varscan2
- AIRE | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); catalogued as rs1255656504; called by muse, mutect2, varscan2
- AL121899.2 | c.585G>A p.W195* | Nonsense Mutation (SNP) | VAF 100/264 reads (38%) | catalogued as rs867276818, COSV67349713; called by muse, mutect2, varscan2
- AL121899.2 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 169/465 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV67349736, COSV67351744; called by muse, mutect2, varscan2
- ALAS2 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.473); catalogued as rs1338391423, CM992590; called by muse, varscan2
- ALDH16A1 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 134/402 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.84); catalogued as rs776285715; called by muse, mutect2, varscan2
- ALDH1L1 | c.2621G>A p.G874E | Missense Mutation (SNP) | VAF 106/297 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1314519394; called by muse, mutect2, varscan2
- ALDH3A1 | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs776938032, COSV56736168; called by muse, mutect2, varscan2
- ALDH4A1 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV51889786; called by muse, mutect2, varscan2
- ALDOB | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 129/388 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV66398658; called by muse, mutect2, varscan2
- ALG13 | c.3049C>T p.P1017S | Missense Mutation (SNP) | VAF 149/419 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV52638179, COSV52639551; called by muse, mutect2, varscan2
- ALLC | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 109/359 reads (30%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs540254607; called by muse, mutect2, varscan2
- ALLC | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 111/358 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.079); catalogued as COSV52998854; called by muse, mutect2, varscan2
- ALOX12B | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.496); catalogued as COSV59874557; called by muse, varscan2
- ALS2 | c.4087G>A p.E1363K | Missense Mutation (SNP) | VAF 89/214 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV51890083; called by muse, mutect2, varscan2
- AMPH | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 130/484 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.079); catalogued as rs372537853; called by muse, mutect2
- AMZ1 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 336/581 reads (58%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs777906573; called by muse, mutect2, varscan2
- ANK1 | c.4094C>T p.P1365L | Missense Mutation (SNP) | VAF 82/246 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs771548626; called by muse, varscan2
- ANK2 | c.6820C>T p.R2274C | Missense Mutation (SNP) | VAF 151/385 reads (39%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs140258681; called by muse, mutect2, varscan2
- ANK3 | c.7537G>A p.E2513K | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.452); catalogued as COSV55058315; called by mutect2, varscan2
- ANKEF1 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 114/368 reads (31%) | catalogued as rs370343501; called by muse, mutect2, varscan2
- ANKFN1 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 115/455 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as rs1267516997, COSV59444158; called by muse, mutect2, varscan2
- ANKFN1 | c.3760G>A p.E1254K (on ENST00000653862; = p.E1107K on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/565 reads (29%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.065); catalogued as rs772128737; called by muse, mutect2, varscan2
- ANKMY2 | c.823C>T p.P275S | Missense Mutation (SNP) | VAF 121/494 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV61011967; called by muse, mutect2, varscan2
- ANKRD11 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 111/202 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs765145162; called by muse, mutect2, varscan2
- ANKRD11 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 174/289 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56374517; called by muse, mutect2, varscan2
- ANKRD20A4P | c.1771G>A p.E591K | Missense Mutation (SNP) | VAF 47/377 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1429448767; called by muse, mutect2, varscan2
- ANKRD30A | c.4156C>T p.Q1386* (on ENST00000611781; = p.Q1330* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 33/96 reads (34%) | catalogued as COSV64621256; called by muse, mutect2, varscan2
- ANKRD30B | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.801); catalogued as COSV62811725; called by muse, mutect2, varscan2
- ANKRD34C | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 131/329 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs578238681, COSV69854460; called by muse, mutect2, varscan2
- ANKRD35 | c.1253G>A p.G418E | Missense Mutation (SNP) | VAF 184/1074 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.099); catalogued as rs144568877, COSV62909755; called by muse, mutect2, varscan2
- ANKRD45 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 127/381 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV60960199; called by muse, mutect2, varscan2
- ANO2 | c.692C>T p.S231L (on ENST00000356134 / NM_001278597.3; = p.S235L on NM_001278596.3) | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.025); catalogued as rs772006493, COSV59012074, COSV59032011; called by muse, varscan2
- ANO3 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 75/209 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1193464179; called by muse, mutect2, varscan2
- ANO8 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 103/308 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99344827; called by muse, mutect2, varscan2
- AP3D1 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100642669; called by muse, mutect2, varscan2
- AP3D1 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 132/378 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.401); catalogued as COSV61430653; called by muse, varscan2
- APBA1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 149/367 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs767378055; called by muse, mutect2, varscan2
- APBA1 | c.715G>A p.D239N | Missense Mutation (SNP) | VAF 196/510 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.894); catalogued as rs1242573569, COSV55228372; called by muse, mutect2, varscan2
- APLF | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 130/361 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1428620697; called by muse, mutect2, varscan2
- APLP2 | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 85/158 reads (54%) | catalogued as COSV53842376; called by muse, mutect2, varscan2
- APOBR | c.2926G>A p.E976K (on ENST00000431282; = p.E985K on NM_018690.4) | Missense Mutation (SNP) | VAF 135/325 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.316); catalogued as rs1463817760, COSV100112701; called by muse, mutect2, varscan2
- AQP11 | c.63G>C p.M21I | Missense Mutation (SNP) | VAF 150/413 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs199510186; called by muse, mutect2, varscan2
- AR | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 184/494 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as HM971841, COSV65955002; called by muse, mutect2, varscan2
- AR | c.2453C>T p.P818L | Missense Mutation (SNP) | VAF 78/175 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CD1515318, HM060563; called by muse, mutect2, varscan2
- ARAP1 | c.3579C>T p.V1193= (on ENST00000393609 / NM_001040118.2; = p.V948= on NM_015242.4) | Splice Region (SNP) | VAF 84/259 reads (32%) | catalogued as COSV61989138; called by muse, mutect2, varscan2
- ARFGEF1 | c.3518C>T p.S1173L | Missense Mutation (SNP) | VAF 95/278 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51603747; called by muse, mutect2, varscan2
- ARFGEF3 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 141/253 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs1164308106, COSV99293078; called by muse, mutect2, varscan2
- ARFGEF3 | c.6475C>T p.R2159C | Missense Mutation (SNP) | VAF 130/209 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776499591, COSV52462151; called by muse, mutect2, varscan2
- ARHGAP29 | c.2591C>T p.S864F | Missense Mutation (SNP) | VAF 161/464 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1278238925, COSV53113074; called by muse, mutect2, varscan2
- ARHGAP35 | c.4037-1G>A p.X1346_splice | Splice Site (SNP) | VAF 69/213 reads (32%) | catalogued as COSV68336140; called by muse, mutect2, varscan2
- ARHGAP44 | c.1497G>A p.M499I | Missense Mutation (SNP) | VAF 90/253 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs1159638916, COSV52394133; called by muse, mutect2, varscan2
- ARHGAP44 | c.2422G>A p.D808N | Missense Mutation (SNP) | VAF 130/347 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52395186; called by muse, mutect2, varscan2
- ARHGEF15 | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 137/384 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs779116620; called by muse, mutect2, varscan2
- ARHGEF35 | c.731G>A p.G244E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs879452879; called by mutect2, varscan2
- ARHGEF38 | c.1220C>T p.S407L | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs909116032, COSV70364887; called by muse, mutect2, varscan2
- ARHGEF5 | c.311G>T p.W104L | Missense Mutation (SNP) | VAF 67/488 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as rs548124751; called by muse, mutect2, varscan2
- ARHGEF5 | c.3595C>T p.H1199Y | Missense Mutation (SNP) | VAF 94/606 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50207585; called by muse, varscan2
- ARHGEF5 | c.3635A>G p.N1212S | Missense Mutation (SNP) | VAF 80/545 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); catalogued as rs758769269; called by muse, varscan2
- ARID1B | c.1564G>A p.V522M | Missense Mutation (SNP) | VAF 97/174 reads (56%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV99269249; called by muse, mutect2, varscan2
- ARID1B | c.2894C>T p.P965L | Missense Mutation (SNP) | VAF 130/207 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.573); catalogued as COSV51647366, COSV51659778; called by muse, mutect2, varscan2
- ARL14 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 160/400 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57899830; called by muse, mutect2, varscan2
- ARMC4 | c.2629C>T p.R877C | Missense Mutation (SNP) | VAF 76/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776670080, COSV59464456; called by muse, varscan2
- ARMCX3 | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 154/479 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1556038584, COSV57869777; called by muse, mutect2, varscan2
- ARSB | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 104/276 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1323312212; called by muse, mutect2, varscan2
- ARSF | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 160/410 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as rs985603182, COSV63839651; called by muse, mutect2, varscan2
- ARSJ | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 174/474 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.332); catalogued as rs748760887; called by muse, mutect2, varscan2
- ASIC2 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 150/440 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV63316015; called by muse, mutect2, varscan2
- ASTN2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 112/298 reads (38%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.054); catalogued as rs372229820, COSV57799341; called by muse, mutect2, varscan2
- ASZ1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 43/189 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as rs200268860; called by muse, varscan2
- ATCAY | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 128/332 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs776589438; called by muse, mutect2, varscan2
- ATF6B | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 187/789 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.525); catalogued as COSV64352062; called by muse, mutect2, varscan2
- ATG14 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 60/202 reads (30%) | catalogued as COSV55956713, COSV99902787; called by muse, mutect2, varscan2
- ATP2B2 | c.2053G>A p.E685K (on ENST00000352432; = p.E651K on NM_001683.5) | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs752661102, COSV59493351; called by muse, mutect2, varscan2
- ATP2B2 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 125/308 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV59490313, COSV99080519; called by muse, mutect2, varscan2
- ATP2B3 | c.3298G>A p.G1100S | Missense Mutation (SNP) | VAF 168/450 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as COSV54863851; called by muse, mutect2, varscan2
- ATP8B4 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1196906971; called by muse, mutect2, varscan2
- ATRX | c.1297A>G p.K433E | Missense Mutation (SNP) | VAF 147/415 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs898727479, COSV100970814; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AXIN2 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 197/677 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.694); catalogued as rs780894296, COSV61060100; called by muse, mutect2, varscan2
- AXL | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 192/524 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1430166029; called by muse, mutect2, varscan2
- B3GALT1 | c.191A>C p.E64A | Missense Mutation (SNP) | VAF 130/380 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs757583316; called by muse, mutect2, varscan2
- BAAT | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 124/357 reads (35%) | catalogued as rs764187428, COSV52288701; called by muse, mutect2, varscan2
- BAG5 | c.1168C>T p.R390* | Nonsense Mutation (SNP) | VAF 108/319 reads (34%) | catalogued as rs182208325, COSV54570184; called by muse, mutect2, varscan2
- BARX2 | c.716G>A p.G239E | Missense Mutation (SNP) | VAF 174/282 reads (62%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs751855579, COSV55651823; called by muse, varscan2
- BBOF1 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 107/314 reads (34%) | catalogued as rs1329550968; called by muse, mutect2, varscan2
- BBOX1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 104/288 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs978954275, COSV54190208; called by muse, mutect2, varscan2
- BCAM | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 138/362 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs1368885073; called by muse, varscan2
- BCLAF1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as COSV62146741; called by muse, mutect2, varscan2
- BCOR | c.5194G>A p.E1732K (on ENST00000378444 / NM_001123385.2; = p.E1698K on NM_017745.6) | Missense Mutation (SNP) | VAF 186/506 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs1437936868, COSV100653058, COSV60700979; called by muse, mutect2, varscan2
- BEND4 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 177/424 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.16); catalogued as rs771898046, COSV72468916, COSV72469273; called by muse, mutect2, varscan2
- BICC1 | c.2461G>C p.G821R | Missense Mutation (SNP) | VAF 163/454 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54062829; called by muse, mutect2, varscan2
- BIRC6 | c.12367G>A p.E4123K | Missense Mutation (SNP) | VAF 149/413 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs933129887; called by muse, mutect2, varscan2
- BMPER | c.1055G>A p.G352E | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.46); catalogued as COSV51813906, COSV51817713; called by muse, mutect2, varscan2
- BNIPL | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 91/592 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs201384045, COSV54848559; called by muse, mutect2, varscan2
- BRF1 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 107/295 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs774447444, COSV100527698; called by muse, mutect2, varscan2
- BRINP1 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 121/337 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); catalogued as COSV56294559; called by muse, mutect2, varscan2
- BRINP1 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 137/434 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as rs764927108, COSV56297792; called by muse, mutect2, varscan2
- BRIP1 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 168/324 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs1357919929, COSV52007556; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BSG | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 116/351 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs1157839560; called by muse, mutect2, varscan2
- BSN | c.4538C>T p.P1513L | Missense Mutation (SNP) | VAF 162/489 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs986258487; called by muse, mutect2, varscan2
- BSND | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 137/371 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760023611, COSV64870346; called by muse, mutect2, varscan2
- BTBD11 | c.2566G>A p.E856K (on ENST00000280758 / NM_001018072.2; = p.E393K on NM_001017523.2) | Missense Mutation (SNP) | VAF 152/420 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.473); catalogued as COSV99774720; called by muse, mutect2, varscan2
- BTBD18 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 139/372 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1208658399; called by muse, mutect2, varscan2
- BTC | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67547272; called by muse, mutect2, varscan2
- BUD13 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 142/238 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.137); catalogued as rs1286724590; called by muse, mutect2, varscan2
- C10orf71 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 178/470 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV60511404; called by muse, varscan2
- C10orf88 | c.736T>A p.L246I | Missense Mutation (SNP) | VAF 113/333 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.053); catalogued as rs1330043819; called by muse, mutect2, varscan2
- C12orf40 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61132330; called by muse, mutect2, varscan2
- C12orf40 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV61131034; called by muse, mutect2, varscan2
- C12orf40 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV61139258; called by muse, mutect2, varscan2
- C12orf40 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV61129266; called by muse, mutect2, varscan2
- C12orf42 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.181); catalogued as COSV59381039; called by muse, mutect2, varscan2
- C16orf46 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 162/457 reads (35%) | catalogued as rs145595395; called by muse, mutect2, varscan2
- C1S | c.1736C>T p.A579V | Missense Mutation (SNP) | VAF 193/495 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as COSV61071807; called by muse, mutect2, varscan2
- C1orf68 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 809/1071 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs987730232; called by muse, mutect2, varscan2
- C1orf87 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 100/310 reads (32%) | catalogued as rs147997086, COSV64596556; called by muse, varscan2
- C1orf94 | c.1621C>T p.P541S (on ENST00000488417 / NM_001134734.2; = p.P351S on NM_032884.5) | Missense Mutation (SNP) | VAF 158/406 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV64913054; called by muse, mutect2, varscan2
- C20orf144 | c.92C>G p.S31W | Missense Mutation (SNP) | VAF 128/347 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs761579956, COSV99864740; called by muse, mutect2, varscan2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 130/356 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- C4orf54 | c.2513C>T p.S838F | Missense Mutation (SNP) | VAF 120/318 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV72766827; called by muse, mutect2, varscan2
- C5orf46 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as rs1470441877; called by muse, mutect2, varscan2
- C6 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 106/398 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1363501052; called by muse, mutect2, varscan2
- C6 | c.2488C>T p.H830Y | Missense Mutation (SNP) | VAF 248/467 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as COSV54710897; called by muse, mutect2, varscan2
- C7 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 79/322 reads (25%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV57474147; called by muse, mutect2, varscan2
- C8orf34 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV61379409; called by muse, mutect2, varscan2
- C8orf34 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 89/315 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.007); catalogued as COSV57406392; called by muse, mutect2, varscan2
- CABP4 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 154/386 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1347952534, COSV56888159; called by muse, mutect2, varscan2
- CABS1 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 116/331 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.318); catalogued as COSV99909111; called by muse, mutect2, varscan2
- CABS1 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 116/332 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV56733585; called by muse, mutect2, varscan2
- CACNA1B | c.6475G>A p.G2159R | Missense Mutation (SNP) | VAF 132/400 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.355); catalogued as COSV53141247; called by muse, varscan2
- CACNA1D | c.2120G>A p.W707* (on ENST00000350061 / NM_001128840.3; = p.W727* on NM_000720.4) | Nonsense Mutation (SNP) | VAF 108/294 reads (37%) | catalogued as COSV55463867; called by muse, mutect2, varscan2
- CACNA1E | c.5470G>A p.G1824S | Missense Mutation (SNP) | VAF 146/198 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); catalogued as COSV100703440; called by mutect2, varscan2
- CACNA2D3 | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 115/297 reads (39%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.903); catalogued as rs753921913, COSV55513596; called by muse, mutect2, varscan2
- CACNA2D3 | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 114/287 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs148102086; called by muse, mutect2, varscan2
- CACNA2D3 | c.2425G>A p.E809K | Missense Mutation (SNP) | VAF 108/305 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1225594190, COSV55560112, COSV99872867; called by muse, mutect2, varscan2
- CACNG3 | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 181/519 reads (35%) | catalogued as COSV50069711; called by muse, mutect2, varscan2
- CACNG5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 104/476 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs377716365; called by muse, mutect2, varscan2
- CALCR | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 112/394 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV64006742; called by muse, mutect2, varscan2
- CALCR | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 232/410 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as rs972946; called by muse, mutect2, varscan2
- CALHM1 | c.986G>A p.G329E | Missense Mutation (SNP) | VAF 180/463 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.231); catalogued as rs991786164; called by muse, mutect2, varscan2
- CALN1 | c.148C>T p.R50W (on ENST00000329008 / NM_001017440.3; = p.R92W on NM_031468.4) | Missense Mutation (SNP) | VAF 117/402 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61146464, COSV61158154; called by muse, mutect2, varscan2
- CAMK2B | c.1561C>T p.P521S | Missense Mutation (SNP) | VAF 125/486 reads (26%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.011); catalogued as rs1378275801; called by muse, mutect2, varscan2
- CAP2 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV57737962; called by muse, mutect2, varscan2
- CAPN12 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 143/422 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs368225374; called by muse, mutect2, varscan2
- CAPSL | c.153G>A p.M51I | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV101274240; called by muse, mutect2, varscan2
- CARD9 | c.1408C>T p.Q470* | Nonsense Mutation (SNP) | VAF 159/457 reads (35%) | catalogued as COSV100261340; called by muse, mutect2, varscan2
- CASP1 | c.1121G>A p.R374Q (on ENST00000436863 / NM_033292.4; = p.R353Q on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/142 reads (65%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1024902270, COSV52830913, COSV99507165; called by muse, mutect2, varscan2
- CASP14 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 127/401 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV55664932; called by muse, mutect2, varscan2
- CASR | c.2497C>T p.P833S (on ENST00000490131; = p.P910S on NM_000388.4) | Missense Mutation (SNP) | VAF 162/478 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.591); catalogued as COSV56141975; called by muse, mutect2, varscan2
- CATSPER1 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 185/508 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as rs1565074732; called by muse, mutect2, varscan2
- CBL | c.1178T>G p.I393S | Missense Mutation (SNP) | VAF 102/162 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50634390, COSV50677600, COSV99876541; called by muse, mutect2, varscan2
- CBWD3 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 22/218 reads (10%) | catalogued as rs1554669939; called by muse, mutect2, varscan2
- CCDC102B | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV60140280; called by muse, mutect2, varscan2
- CCDC105 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 89/280 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as COSV52963797; called by muse, mutect2, varscan2
- CCDC105 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 111/334 reads (33%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV52963627; called by muse, mutect2, varscan2
- CCDC105 | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 114/284 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.813); catalogued as COSV52963953; called by muse, mutect2, varscan2
- CCDC144A | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 201/513 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as COSV61403849; called by muse, mutect2, varscan2
- CCDC146 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 114/431 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1027523120, COSV99593420; called by muse, mutect2, varscan2
- CCDC154 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs561677923, COSV101209693, COSV101209706; called by muse, mutect2, varscan2
- CCDC168 | c.12280C>T p.P4094S | Missense Mutation (SNP) | VAF 110/288 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as rs984819285; called by muse, mutect2, varscan2
- CCDC168 | c.5708C>T p.S1903L | Missense Mutation (SNP) | VAF 133/331 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV70554792; called by muse, mutect2, varscan2
- CCDC168 | c.5033G>A p.G1678D | Missense Mutation (SNP) | VAF 116/392 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70555029; called by muse, mutect2, varscan2
- CCDC185 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 178/476 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs557959151, COSV64821620; called by muse, varscan2
- CCDC185 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 326/423 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs989181102; called by muse, mutect2, varscan2
- CCDC39 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV56495026; called by muse, mutect2, varscan2
- CCDC57 | c.2563G>A p.E855K | Missense Mutation (SNP) | VAF 53/209 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as rs1218913231; called by muse, mutect2, varscan2
- CCDC60 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 122/335 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.346); catalogued as rs141830259; called by muse, mutect2, varscan2
- CCDC63 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 176/464 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); catalogued as rs137859782; called by muse, mutect2, varscan2
- CCDC73 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs867778040, COSV100067156; called by muse, mutect2, varscan2
- CCDC73 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58795949; called by muse, mutect2, varscan2
- CCDC81 | c.1861C>T p.R621W (on ENST00000445632 / NM_001156474.2; = p.R531W on NM_021827.4) | Missense Mutation (SNP) | VAF 137/219 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs565863880; called by muse, mutect2, varscan2
- CCER1 | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 172/443 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV62646799; called by muse, mutect2, varscan2
- CCT8L2 | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 106/344 reads (31%) | catalogued as rs779930741; called by muse, varscan2
- CD163 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 125/332 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765869382, COSV63136320; called by muse, mutect2, varscan2
- CD163 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 148/332 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222044619, COSV63136375; called by muse, mutect2, varscan2
- CD1D | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 571/700 reads (82%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.608); catalogued as rs769399031, COSV63808849; called by muse, mutect2, varscan2
- CD300A | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 148/625 reads (24%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV60409388; called by muse, mutect2, varscan2
- CD300A | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 96/375 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV60410429; called by muse, mutect2, varscan2
- CD33 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 106/291 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV51803585; called by muse, mutect2, varscan2
- CD7 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 205/865 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.803); catalogued as rs536476554, COSV53939531; called by muse, mutect2, varscan2
- CD70 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 118/301 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1478106216; called by muse, mutect2, varscan2
- CD86 | c.744G>A p.W248* (on ENST00000330540 / NM_175862.5; = p.W242* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 100/304 reads (33%) | catalogued as COSV52605989; called by muse, mutect2, varscan2
- CD93 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 197/537 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.232); catalogued as rs746085953; called by muse, mutect2, varscan2
- CDC42BPA | c.5194C>T p.P1732S (on ENST00000334218 / NM_001366019.2; = p.P1719S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 217/296 reads (73%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV62004388; called by muse, mutect2, varscan2
- CDCP1 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 115/345 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56104212; called by muse, mutect2, varscan2
- CDH10 | c.2219G>A p.G740E | Missense Mutation (SNP) | VAF 151/419 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52570603, COSV52576617; called by muse, mutect2, varscan2
- CDH10 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 124/334 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100050393, COSV52570059; called by muse, mutect2, varscan2
- CDH12 | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 96/302 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66452782; called by muse, mutect2, varscan2
- CDH18 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 119/352 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.219); catalogued as rs866875588, COSV56959856; called by muse, mutect2, varscan2
- CDH20 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 71/207 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53006859; called by muse, mutect2, varscan2
- CDH22 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 127/300 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.322); catalogued as COSV64836613; called by muse, mutect2, varscan2
- CDH7 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.277); catalogued as COSV100542365, COSV59884609; called by muse, mutect2, varscan2
- CDH8 | c.2036C>T p.A679V | Missense Mutation (SNP) | VAF 162/427 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54867989; called by muse, mutect2, varscan2
- CDH9 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 117/350 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs762037380, COSV50252306, COSV50267855; called by muse, mutect2, varscan2
- CDHR4 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 181/438 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV58526984; called by muse, mutect2, varscan2
- CDK19 | c.736C>T p.P246S | Missense Mutation (SNP) | VAF 92/174 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60450842; called by muse, mutect2, varscan2
- CDK20 | c.776C>T p.P259L (on ENST00000325303 / NM_001039803.3; = p.P238L on NM_012119.4) | Missense Mutation (SNP) | VAF 155/435 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs371639597; called by muse, mutect2, varscan2
- CDKAL1 | c.1459A>T p.M487L | Missense Mutation (SNP) | VAF 144/558 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs751558817; called by muse, mutect2, varscan2
- CDKL2 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1377013323; called by muse, mutect2, varscan2
- CDRT15L2 | c.116C>T p.P39L | Missense Mutation (SNP) | VAF 157/472 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as rs762314106; called by muse, varscan2
- CDX4 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 201/560 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); catalogued as rs1436701181; called by muse, mutect2, varscan2
- CEACAM8 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 128/348 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV54991112; called by muse, mutect2
- CELA3B | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 119/330 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as rs140120229; called by muse, mutect2, varscan2
- CELF3 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 170/1066 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.403); catalogued as COSV99310091; called by muse, mutect2, varscan2
- CEP152 | c.1480C>T p.P494S | Missense Mutation (SNP) | VAF 100/287 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.31); catalogued as rs767472633; called by muse, mutect2, varscan2
- CEP70 | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.791); catalogued as COSV53876341, COSV53877247; called by muse, mutect2, varscan2
- CERKL | c.1537G>A p.D513N (on ENST00000339098 / NM_001030311.2; = p.D487N on NM_201548.5) | Missense Mutation (SNP) | VAF 109/341 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as COSV59212471; called by muse, mutect2, varscan2
- CFAP44 | c.3326C>T p.T1109I | Missense Mutation (SNP) | VAF 129/368 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1322853658, COSV67249007; called by muse, mutect2, varscan2
- CFAP47 | c.8857C>T p.P2953S | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.009); catalogued as COSV66218077; called by muse, mutect2, varscan2
- CFAP52 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 151/418 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55346282; called by muse, mutect2, varscan2
- CFAP54 | c.6419G>A p.G2140E | Missense Mutation (SNP) | VAF 90/224 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61573137; called by muse, mutect2, varscan2
- CFAP58 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.287); catalogued as COSV57212217, COSV57212542; called by muse, varscan2
- CFAP61 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 77/237 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs371793125, COSV55639118; called by muse, mutect2, varscan2
- CFAP70 | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 104/237 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV60282542; called by muse, mutect2, varscan2
- CFHR4 | c.1274G>A p.G425E (on ENST00000367416 / NM_001201551.2; = p.G179E on NM_006684.5) | Missense Mutation (SNP) | VAF 108/284 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52235868; called by muse, varscan2
- CFP | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 179/483 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs750018657; called by muse, mutect2, varscan2
- CGN | c.2023C>T p.R675* | Nonsense Mutation (SNP) | VAF 161/1060 reads (15%) | catalogued as rs569243416, COSV54974162, COSV99642215; called by muse, mutect2, varscan2
- CHGB | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 157/434 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66759603; called by muse, mutect2, varscan2
- CHI3L1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 736/806 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs142178236; called by muse, mutect2, varscan2
- CLCN6 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 134/378 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV56743698; called by muse, mutect2, varscan2
- CLCN7 | c.981C>T p.I327= | Splice Region (SNP) | VAF 106/297 reads (36%) | catalogued as rs776917548, COSV51971756; called by muse, mutect2, varscan2
- CLCNKA | c.1681G>A p.D561N | Missense Mutation (SNP) | VAF 146/407 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.285); catalogued as COSV58892355; called by muse, varscan2
- CLDN16 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 104/283 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs761824865, COSV53227483; called by muse, mutect2, varscan2
- CLDN18 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 123/405 reads (30%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.983); catalogued as rs369029508, COSV59304518; called by muse, mutect2, varscan2
- CLEC4F | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 111/337 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV55479695; called by muse, mutect2, varscan2
- CLEC5A | c.352C>T p.L118F | Missense Mutation (SNP) | VAF 172/298 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV69396857, COSV69397801; called by muse, mutect2, varscan2
- CLECL1 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 152/377 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as COSV59931174, COSV59931513; called by muse, mutect2, varscan2
- CLK3 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 176/480 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1166587974, COSV61414220; called by muse, varscan2
- CLSTN1 | c.1915C>T p.P639S (on ENST00000377298 / NM_001009566.3; = p.P629S on NM_014944.4) | Missense Mutation (SNP) | VAF 98/302 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1286269199, COSV63647573; called by muse, mutect2, varscan2
- CLYBL | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 120/365 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867229590; called by muse, mutect2, varscan2
- CMC4 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 150/447 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.192); catalogued as COSV62898628; called by muse, mutect2, varscan2
- CMYA5 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 144/392 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV101483736; called by muse, mutect2, varscan2
- CNBD1 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV73075917; called by muse, mutect2, varscan2
- CNGB1 | c.2910G>A p.M970I | Missense Mutation (SNP) | VAF 128/329 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs756942679, COSV51900934, COSV51902161; called by muse, mutect2, varscan2
- CNMD | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 147/406 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs748967137, COSV60131650; called by muse, mutect2, varscan2
- CNTN4 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1316109477, COSV100639121, COSV61878444; called by muse, mutect2, varscan2
- CNTN5 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 111/196 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54291760; called by muse, mutect2, varscan2
- CNTN6 | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 91/242 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767478104; called by muse, mutect2, varscan2
- CNTNAP2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 117/452 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV62143246; called by muse, varscan2
- CNTNAP2 | c.3314G>A p.R1105K | Missense Mutation (SNP) | VAF 141/542 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.289); catalogued as COSV100673940; called by muse, mutect2, varscan2
- CNTNAP5 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 82/248 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs765130255, COSV70494484; called by muse, mutect2, varscan2
- CNTRL | c.4499C>T p.S1500L | Missense Mutation (SNP) | VAF 84/197 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751035332; called by muse, mutect2, varscan2
- CNTRL | c.5240C>T p.S1747F | Missense Mutation (SNP) | VAF 106/295 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1009808549; called by muse, mutect2, varscan2
- COG5 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 118/492 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs751598750; called by muse, mutect2, varscan2
- COL10A1 | c.728T>C p.M243T | Missense Mutation (SNP) | VAF 114/194 reads (59%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99684316; called by muse, mutect2, varscan2
- COL11A2 | c.3367G>A p.G1123R (on ENST00000341947 / NM_080680.3; = p.G1016R on NM_080679.2) | Missense Mutation (SNP) | VAF 123/461 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV59500078; called by muse, mutect2, varscan2
- COL15A1 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.14); catalogued as COSV66646293; called by muse, mutect2, varscan2
- COL22A1 | c.3076G>A p.D1026N | Missense Mutation (SNP) | VAF 78/286 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.516); catalogued as rs1281203824; called by muse, mutect2, varscan2
- COL22A1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 222/559 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1224742768; called by muse, mutect2, varscan2
- COL23A1 | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 156/438 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.246); catalogued as COSV66799555; called by muse, mutect2, varscan2
- COL2A1 | c.2411G>A p.G804E | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1286544132, CM940303, COSV61534890; called by muse, mutect2, varscan2
- COL3A1 | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.918); catalogued as rs1559052973; called by muse, mutect2, varscan2
- COL4A1 | c.3122G>A p.G1041E | Missense Mutation (SNP) | VAF 173/453 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM130953, COSV65433221; called by muse, mutect2, varscan2
- COL4A2 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 141/333 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as rs376081023; called by muse, mutect2, varscan2
- COL4A5 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 100/263 reads (38%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.572); catalogued as COSV60370845; called by muse, varscan2
- COL5A1 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 164/399 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV65668334; called by muse, mutect2, varscan2
- COL6A5 | c.4772G>A p.G1591E | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55214567; called by muse, mutect2, varscan2
- COL9A1 | c.2374C>T p.P792S | Missense Mutation (SNP) | VAF 261/522 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1250233361; called by muse, mutect2, varscan2
- COL9A1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 269/452 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs780899445, COSV61831236; called by muse, mutect2, varscan2
- COMTD1 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 132/547 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.42); catalogued as rs751019814; called by muse, mutect2, varscan2
- CPEB2 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 74/222 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.068); catalogued as rs1305311712; called by muse, mutect2, varscan2
- CPED1 | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 87/309 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100121629; called by muse, mutect2, varscan2
- CPHXL | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 135/393 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs542417968; called by muse, mutect2, varscan2
- CPZ | c.271G>A p.G91S (on ENST00000360986 / NM_001014447.3; = p.G80S on NM_003652.3) | Missense Mutation (SNP) | VAF 226/557 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs773066083; called by muse, mutect2, varscan2
- CRAMP1 | c.2834C>T p.P945L | Missense Mutation (SNP) | VAF 122/326 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs1260699884; called by muse, mutect2, varscan2
- CRAMP1 | c.2905C>T p.P969S | Missense Mutation (SNP) | VAF 165/388 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); catalogued as rs752700402; called by muse, mutect2, varscan2
- CREBBP | c.3620C>T p.S1207F | Missense Mutation (SNP) | VAF 102/302 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52132205; called by muse, mutect2, varscan2
- CROCC2 | c.3973G>A p.D1325N | Missense Mutation (SNP) | VAF 95/308 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs915089733; called by muse, mutect2, varscan2
- CRTC1 | c.935G>A p.S312N | Missense Mutation (SNP) | VAF 149/437 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); catalogued as rs1209615146; called by muse, mutect2, varscan2
- CSH1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 136/553 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.357); catalogued as COSV100298179; called by muse, mutect2, varscan2
- CSMD1 | c.3818C>T p.S1273L (on ENST00000520002; = p.S1272L on NM_033225.6) | Missense Mutation (SNP) | VAF 87/151 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.265); catalogued as rs371526159, COSV100146309, COSV59323979; called by muse, mutect2, varscan2
- CSMD2 | c.8423G>A p.G2808E | Missense Mutation (SNP) | VAF 164/411 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53977100; called by muse, mutect2, varscan2
- CSMD2 | c.4006G>A p.G1336R | Missense Mutation (SNP) | VAF 149/420 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs368584183; called by muse, mutect2, varscan2
- CSMD3 | c.9958C>T p.P3320S (on ENST00000297405 / NM_001363185.1; = p.P3151S on NM_052900.3) | Missense Mutation (SNP) | VAF 148/374 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as COSV52271134; called by muse, mutect2, varscan2
- CST8 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 107/333 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs267605858; called by muse, mutect2, varscan2
- CT47B1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 134/304 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.096); catalogued as COSV100989040; called by muse, mutect2, varscan2
- CTAGE6 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 80/459 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1166358860; called by muse, mutect2, varscan2
- CTAGE9 | c.828G>A p.M276I | Missense Mutation (SNP) | VAF 147/400 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.036); catalogued as rs1272015934; called by muse, mutect2, varscan2
- CTNND2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 131/197 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.055); catalogued as COSV58877143; called by muse, mutect2, varscan2
- CUX2 | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 216/547 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.914); catalogued as rs1299343683; called by muse, mutect2, varscan2
- CYP11B2 | c.434A>C p.N145T | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010875; called by muse, mutect2, varscan2
- CYP2C8 | c.213G>A p.M71I | Missense Mutation (SNP) | VAF 116/316 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV64878575; called by muse, mutect2, varscan2
- CYP2C9 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233116373, COSV53253897; called by muse, mutect2, varscan2
- CYP2F1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 136/383 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs747690814; called by muse, mutect2, varscan2
- CYP4B1 | c.180G>A p.E60= | Splice Region (SNP) | VAF 104/239 reads (44%) | catalogued as rs751134907; called by muse, varscan2
- CYP4X1 | c.1352C>T p.S451L | Missense Mutation (SNP) | VAF 69/220 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV64149979; called by muse, mutect2, varscan2
- CYP4Z1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 161/394 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs571972072, COSV61963888; called by muse, mutect2, varscan2
- CYTIP | c.251A>T p.D84V | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1290506636; called by muse, mutect2, varscan2
- DACH1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 131/323 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV100498158; called by muse, mutect2, varscan2
- DBH | c.339G>T p.A113= | Splice Region (SNP) | VAF 90/242 reads (37%) | catalogued as rs747816048, COSV99707947; called by muse, varscan2
- DCAF11 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 106/366 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758178338; called by muse, mutect2, varscan2
- DCAF8L1 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 203/535 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as rs142810555, COSV101491563; called by muse, mutect2, varscan2
- DCC | c.3119G>A p.R1040K | Missense Mutation (SNP) | VAF 78/236 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV59084729; called by muse, mutect2
- DCHS1 | c.293G>A p.S98N | Missense Mutation (SNP) | VAF 131/404 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs902371714; called by muse, mutect2, varscan2
- DCLRE1A | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 100/270 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs916928686, COSV63749700; called by muse, mutect2, varscan2
- DCX | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 104/289 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.096); catalogued as COSV57573654; called by muse, mutect2, varscan2
- DDX24 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 153/457 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.143); catalogued as rs753312058; called by muse, mutect2, varscan2
- DDX56 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 269/522 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as rs1210747380; called by muse, mutect2, varscan2
- DDX60L | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV52720259; called by muse, mutect2, varscan2
- DEF6 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 200/711 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs557445715, COSV57353411, COSV57355572; called by muse, mutect2, varscan2
- DENND1A | c.1681C>T p.P561S | Missense Mutation (SNP) | VAF 173/489 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.062); catalogued as rs1223049335; called by muse, mutect2, varscan2
- DENND4A | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 75/233 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV71265875; called by muse, mutect2, varscan2
- DEPDC4 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs760521648; called by muse, varscan2
- DGKE | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 83/463 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401113; called by muse, mutect2, varscan2
- DGKK | c.2033C>T p.A678V | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs782695825; called by muse, mutect2, varscan2
- DHCR7 | c.363T>A p.F121L | Missense Mutation (SNP) | VAF 124/356 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as COSV100831776; called by muse, mutect2, varscan2
- DHX58 | c.1273C>T p.Q425* | Nonsense Mutation (SNP) | VAF 109/303 reads (36%) | catalogued as rs1555662363, COSV99288524; called by muse, mutect2, varscan2
- DISP1 | c.3950C>T p.A1317V | Missense Mutation (SNP) | VAF 353/467 reads (76%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as rs772927612; called by muse, mutect2, varscan2
- DMBT1 | c.6446C>T p.S2149F (on ENST00000338354 / NM_001377530.1; = p.S1392F on NM_004406.3) | Missense Mutation (SNP) | VAF 154/398 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as COSV57554211; called by muse, mutect2, varscan2
- DMBX1 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 147/405 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV63602044; called by muse, mutect2, varscan2
- DMD | c.7357G>A p.E2453K | Missense Mutation (SNP) | VAF 122/341 reads (36%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.64); catalogued as COSV58899085; called by muse, mutect2, varscan2
- DNAAF4 | c.424A>G p.K142E | Missense Mutation (SNP) | VAF 53/189 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV58246715; called by muse, mutect2, varscan2
- DNAAF5 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 138/553 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs199585063, COSV52414171; called by muse, varscan2
- DNAH10 | c.3064G>A p.D1022N (on ENST00000409039; = p.D961N on NM_207437.3) | Missense Mutation (SNP) | VAF 121/335 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101292305; called by muse, mutect2, varscan2
- DNAH10 | c.4410G>A p.M1470I (on ENST00000409039; = p.M1409I on NM_207437.3) | Missense Mutation (SNP) | VAF 112/352 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.23); catalogued as COSV68990352; called by muse, mutect2, varscan2
- DNAH14 | c.4406G>A p.G1469E (on ENST00000445597; = p.G1874E on NM_001367479.1) | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV99071033; called by muse, mutect2, varscan2
- DNAH17 | c.4594G>A p.E1532K | Missense Mutation (SNP) | VAF 114/421 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs376750616; called by muse, mutect2, varscan2
- DNAH2 | c.9085G>A p.E3029K | Missense Mutation (SNP) | VAF 133/381 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.401); catalogued as rs1450421365; called by muse, mutect2, varscan2
- DNAH2 | c.10694C>T p.S3565F | Missense Mutation (SNP) | VAF 140/341 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66720348; called by muse, mutect2, varscan2
- DNAH5 | c.8426C>T p.S2809L | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs866324367, COSV54208831; called by muse, mutect2, varscan2
- DNAH6 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as rs760148643; called by muse, mutect2, varscan2
- DNAH6 | c.11431G>A p.D3811N | Missense Mutation (SNP) | VAF 90/268 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52883672; called by muse, varscan2
- DNAH7 | c.10682C>T p.S3561F | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100417697; called by muse, mutect2, varscan2
- DNAH7 | c.9436G>A p.E3146K | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV56764859; called by muse, mutect2, varscan2
- DNAH7 | c.4625C>T p.S1542F | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs749539806, COSV56752041; called by muse, mutect2, varscan2
- DNAH8 | c.2674C>T p.P892S | Missense Mutation (SNP) | VAF 60/247 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1260848543; called by muse, mutect2, varscan2
- DNAH8 | c.7514G>A p.R2505Q | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330298296, COSV59428426; called by muse, mutect2, varscan2
- DNAH8 | c.9874-1G>A p.X3292_splice | Splice Site (SNP) | VAF 108/327 reads (33%) | catalogued as rs1403556539, COSV59469328; called by muse, mutect2, varscan2
- DNAH9 | c.4299G>A p.M1433I | Missense Mutation (SNP) | VAF 145/423 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.381); catalogued as rs1471583348, COSV99303045; called by muse, mutect2, varscan2
- DNAI1 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 124/396 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99647010; called by muse, mutect2, varscan2
- DNAI3 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 127/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs766595867; called by muse, mutect2, varscan2
- DNER | c.1269C>G p.F423L | Missense Mutation (SNP) | VAF 98/264 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV59164964; called by muse, mutect2, varscan2
- DOCK11 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as COSV52244121; called by muse, mutect2, varscan2
- DOCK11 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 122/332 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.562); catalogued as rs142215637; called by muse, mutect2, varscan2
- DOCK11 | c.4079C>T p.S1360L | Missense Mutation (SNP) | VAF 182/462 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV99352608; called by muse, mutect2, varscan2
- DPP10 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs147078556; called by muse, mutect2, varscan2
- DPPA4 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 138/361 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59509498, COSV59511688; called by muse, mutect2, varscan2
- DPYD | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 169/361 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as rs770958862, COSV64594872; called by muse, mutect2, varscan2
- DPYD | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 145/378 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64603724; called by muse, mutect2, varscan2
- DPYD | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 138/367 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV64591966; called by muse, mutect2, varscan2
- DPYD | c.128G>A p.R43K | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.866); catalogued as COSV60076053, COSV60081213; called by muse, mutect2, varscan2
- DRGX | c.462G>T p.L154F | Missense Mutation (SNP) | VAF 167/404 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.617); catalogued as COSV65135846; called by muse, mutect2, varscan2
- DSC1 | c.2025G>A p.M675I | Missense Mutation (SNP) | VAF 130/338 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs771370816, COSV99938425; called by muse, mutect2, varscan2
- DSC1 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 99/247 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1426726054; called by muse, mutect2, varscan2
- DSC1 | c.1036G>A p.D346N | Missense Mutation (SNP) | VAF 83/240 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57148231; called by muse, mutect2, varscan2
- DSC3 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV64571450; called by muse, mutect2, varscan2
- DSPP | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.029); catalogued as rs770712152; called by muse, mutect2, varscan2
- DUXA | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 76/207 reads (37%) | catalogued as rs773479524, COSV101617164, COSV73729528; called by muse, varscan2
- DYNC2I1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 79/364 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs17856461, COSV68107947; called by muse, mutect2, varscan2
- DZIP1 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 231/586 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs749238704, COSV61266804; called by muse, mutect2, varscan2
- E2F4 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 162/473 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as COSV58876353; called by muse, mutect2, varscan2
- E2F8 | c.745C>T p.P249S | Missense Mutation (SNP) | VAF 132/337 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767979515; called by muse, mutect2, varscan2
- EBLN1 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 145/388 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV69370208; called by muse, mutect2, varscan2
- ECE1 | c.2147C>T p.S716F | Missense Mutation (SNP) | VAF 92/290 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV51665767; called by muse, mutect2, varscan2
- ECM2 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 209/584 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs770405287; called by muse, varscan2
- EDA | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 83/233 reads (36%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.999); catalogued as CS113716; called by muse, mutect2, varscan2
- EDEM1 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 130/364 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778392829; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 138/396 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV62567449; called by muse, mutect2, varscan2
- EEF1G | c.554C>T p.P185L | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.02); catalogued as rs1476397110; called by muse, mutect2, varscan2
- EFHB | c.989C>T p.S330L | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs920886420, COSV55553598; called by mutect2, varscan2
- EFHD1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 125/351 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs147850635; called by muse, mutect2, varscan2
- EGFR | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 108/452 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV51794869, COSV51827181; called by muse, mutect2, varscan2
- ELAPOR2 | c.3031G>A p.E1011K (on ENST00000450689 / NM_001142749.3; = p.E844K on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 118/233 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV51884232, COSV51888478; called by muse, mutect2, varscan2
- ELMO1 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 76/346 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs923829225, COSV60294021, COSV60297204; called by muse, mutect2, varscan2
- ELOA2 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 230/586 reads (39%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.717); catalogued as COSV55307398; called by muse, mutect2, varscan2
- EML6 | c.3517G>A p.D1173N | Missense Mutation (SNP) | VAF 92/268 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs117503435; called by muse, mutect2, varscan2
- ENGASE | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 115/457 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as rs762111541, COSV56135016; called by muse, mutect2, varscan2
- ENOX1 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 155/440 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1273945100, COSV54892707; called by muse, mutect2, varscan2
- ENPEP | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 114/316 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs866151750, COSV99488455; called by muse, mutect2, varscan2
- ENPP1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 103/155 reads (66%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs926768412; called by muse, mutect2, varscan2
- EPHA2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 141/358 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV104422089; called by muse, mutect2, varscan2
- EPHA5 | c.1958C>T p.P653L | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56637015, COSV56660311; called by muse, mutect2, varscan2
- EPHA6 | c.2023G>A p.A675T (on ENST00000389672 / NM_001080448.3; = p.A67T on NM_173655.4) | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as rs762672025, COSV101065224; called by muse, mutect2, varscan2
- EPHA6 | c.2387-1G>A p.X796_splice (on ENST00000389672 / NM_001080448.3; = p.X188_splice on NM_173655.4) | Splice Site (SNP) | VAF 65/185 reads (35%) | catalogued as COSV67559133; called by muse, mutect2, varscan2
- EPHA6 | c.2686C>T p.R896W (on ENST00000389672 / NM_001080448.3; = p.R288W on NM_173655.4) | Missense Mutation (SNP) | VAF 117/356 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67593479; called by muse, mutect2, varscan2
- EPHA7 | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs868510824, COSV65177406, COSV65194672; called by muse, mutect2, varscan2
- EPHA7 | c.314C>T p.T105I | Missense Mutation (SNP) | VAF 141/244 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV65168473; called by muse, mutect2, varscan2
- ERC2 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 104/295 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as COSV55652379; called by muse, mutect2, varscan2
- ERCC6L | c.2917G>C p.E973Q | Missense Mutation (SNP) | VAF 143/423 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs930752891; called by muse, mutect2, varscan2
- ERICH3 | c.4430G>A p.G1477E | Missense Mutation (SNP) | VAF 121/328 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs542267741, COSV58604371; called by muse, mutect2, varscan2
- ERICH3 | c.3634G>A p.G1212R | Missense Mutation (SNP) | VAF 187/513 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as COSV58614430; called by muse, mutect2, varscan2
- ERICH3 | c.2783C>T p.S928L | Missense Mutation (SNP) | VAF 200/461 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs754456981, COSV58605032; called by muse, mutect2, varscan2
- ERICH3 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 80/228 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58611116; called by muse, mutect2, varscan2
- ERMP1 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 150/389 reads (39%) | catalogued as rs1401003887; called by muse, mutect2, varscan2
- ESPL1 | c.4688C>T p.P1563L | Missense Mutation (SNP) | VAF 107/305 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs758117110; called by muse, mutect2, varscan2
- ESRRB | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 133/416 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs754177254; called by muse, mutect2, varscan2
- ESRRG | c.918G>A p.M306I | Missense Mutation (SNP) | VAF 120/342 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV63169780; called by muse, mutect2, varscan2
- ETNK1 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 129/354 reads (36%) | catalogued as rs781202115; called by muse, mutect2, varscan2
- ETS2 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 125/362 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.394); catalogued as rs764929763; called by muse, mutect2, varscan2
- ETV1 | c.577C>T p.P193S | Missense Mutation (SNP) | VAF 88/316 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.933); catalogued as COSV54151553, COSV54153632; called by muse, mutect2, varscan2
- EXPH5 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 154/254 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs1220030103, COSV99761888; called by muse, mutect2, varscan2
- FAM135B | c.3755G>A p.G1252E | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52720445, COSV52742237; called by muse, mutect2, varscan2
- FAM13C | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV99513787; called by muse, mutect2, varscan2
- FAM160A2 | c.2140C>T p.P714S (on ENST00000449352 / NM_001098794.2; = p.P728S on NM_032127.4) | Missense Mutation (SNP) | VAF 190/485 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs779830271; called by muse, mutect2, varscan2
- FAM169A | c.1867G>A p.D623N | Missense Mutation (SNP) | VAF 177/481 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs1158509183; called by muse, mutect2, varscan2
- FAM170A | c.984G>A p.R328= | Splice Region (SNP) | VAF 87/256 reads (34%) | catalogued as COSV100088633, COSV58924153; called by muse, mutect2, varscan2
- FAM221B | c.708G>A p.W236* | Nonsense Mutation (SNP) | VAF 134/315 reads (43%) | catalogued as rs1183943625, COSV100941473; called by muse, mutect2, varscan2
- FAM47A | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 190/534 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60500526; called by muse, mutect2, varscan2
- FAM71B | c.1061A>C p.E354A | Missense Mutation (SNP) | VAF 182/461 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV57228182; called by muse, mutect2, varscan2
- FAM83B | c.1019G>A p.R340K | Missense Mutation (SNP) | VAF 85/250 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs749653745; called by muse, mutect2, varscan2
- FAM83B | c.1621C>T p.R541C | Missense Mutation (SNP) | VAF 157/382 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753104783, COSV60922418; called by muse, mutect2, varscan2
- FAM83B | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.118); catalogued as rs776649451, COSV60922779; called by muse, mutect2, varscan2
- FAM83C | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753688609; called by muse, mutect2, varscan2
- FAM83E | c.404C>T p.P135L | Missense Mutation (SNP) | VAF 145/426 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157853973; called by muse, mutect2, varscan2
- FANCB | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 106/293 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs145542355, COSV100146284; called by muse, mutect2, varscan2
- FANCM | c.4187C>T p.P1396L | Missense Mutation (SNP) | VAF 71/192 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs762637141; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FASN | c.2795C>T p.S932F | Missense Mutation (SNP) | VAF 124/414 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as rs146356200; called by muse, mutect2, varscan2
- FAT4 | c.8044G>A p.E2682K | Missense Mutation (SNP) | VAF 137/349 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58707903; called by muse, mutect2, varscan2
- FAT4 | c.8443G>A p.D2815N | Missense Mutation (SNP) | VAF 141/348 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as rs750810694, COSV58681907; called by muse, mutect2, varscan2
- FAT4 | c.11120C>T p.S3707F | Missense Mutation (SNP) | VAF 135/384 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV58708810; called by muse, mutect2, varscan2
- FAT4 | c.11965G>A p.E3989K | Missense Mutation (SNP) | VAF 96/304 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as rs1210398214; called by muse, mutect2, varscan2
- FAT4 | c.13639G>A p.E4547K | Missense Mutation (SNP) | VAF 149/413 reads (36%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.979); catalogued as COSV100630628; called by muse, mutect2, varscan2
- FAT4 | c.13765G>A p.E4589K | Missense Mutation (SNP) | VAF 167/433 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs866092067, COSV58670567; called by muse, mutect2, varscan2
- FAT4 | c.14164G>A p.E4722K | Missense Mutation (SNP) | VAF 123/314 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV58672832, COSV58712191; called by muse, mutect2, varscan2
- FBXW10 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 108/309 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs767437618; called by muse, mutect2, varscan2
- FCRL5 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 150/1032 reads (15%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.761); catalogued as COSV100708925; called by muse, mutect2, varscan2
- FFAR1 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 234/597 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.403); catalogued as rs766312605; called by muse, mutect2, varscan2
- FGD1 | c.2575C>T p.P859S | Missense Mutation (SNP) | VAF 100/284 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.137); catalogued as rs1474169196; called by muse, mutect2, varscan2
- FGF12 | c.295G>A p.E99K (on ENST00000454309 / NM_021032.5; = p.E37K on NM_004113.6) | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as rs865909944, COSV53177161; called by muse, varscan2
- FGF6 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 150/415 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1476081901, COSV57403318; called by muse, mutect2, varscan2
- FGG | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV60196542; called by muse, mutect2, varscan2
- FHAD1 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 97/264 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV58990377; called by muse, varscan2
- FHL5 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 101/196 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.038); catalogued as rs1449031326, COSV58736537; called by muse, mutect2, varscan2
- FIBIN | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 171/494 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as rs140574615; called by muse, mutect2, varscan2
- FILIP1 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 154/227 reads (68%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs771083626; called by muse, mutect2, varscan2
- FKBP4 | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 102/285 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50008834; called by muse, mutect2, varscan2
- FLG | c.9524C>T p.S3175F | Missense Mutation (SNP) | VAF 155/1171 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs139489857; called by muse, mutect2, varscan2
- FLG | c.9386C>T p.S3129L | Missense Mutation (SNP) | VAF 168/1362 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs756193138; called by muse, varscan2
- FLG | c.8627G>A p.G2876E | Missense Mutation (SNP) | VAF 181/2454 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as rs761346065; called by muse, mutect2
- FLG | c.8207G>A p.G2736E | Missense Mutation (SNP) | VAF 85/1598 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.841); catalogued as rs775902916, COSV100910313; called by muse, mutect2
- FLG | c.6553G>A p.G2185R | Missense Mutation (SNP) | VAF 771/1119 reads (69%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.609); catalogued as rs1420330160, COSV64242586; called by muse, mutect2, varscan2
- FLG2 | c.6635G>A p.G2212E | Missense Mutation (SNP) | VAF 132/1056 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.458); catalogued as rs777498449; called by muse, mutect2, varscan2
- FLG2 | c.5983G>A p.G1995R | Missense Mutation (SNP) | VAF 136/989 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs148224294; called by muse, mutect2, varscan2
- FLG2 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 558/949 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.075); catalogued as rs764358914; called by muse, varscan2
- FLI1 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 139/237 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs778290469, COSV100793253, COSV61384581; called by muse, mutect2, varscan2
- FLNA | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 162/400 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs782287086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV56728011; called by muse, mutect2, varscan2
- FMNL2 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 101/252 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs777087549, COSV56491973; called by muse, mutect2, varscan2
- FMO3 | c.560T>G p.V187G | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs769983049, CM093466; called by muse, mutect2, varscan2
- FMO3 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 149/361 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774485262, COSV63007276; called by muse, mutect2, varscan2
- FMOD | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 180/1208 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs774625135, COSV100724653; called by muse, mutect2, varscan2
- FNDC1 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 182/319 reads (57%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV51931131; called by muse, mutect2, varscan2
- FNDC1 | c.4031G>A p.G1344E | Missense Mutation (SNP) | VAF 98/180 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1164221524; called by muse, mutect2, varscan2
- FNDC1 | c.4736C>T p.S1579L | Missense Mutation (SNP) | VAF 105/197 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as rs1376511734, COSV51939404; called by muse, mutect2, varscan2
- FNIP2 | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 126/342 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV52440343; called by muse, mutect2, varscan2
- FOLH1 | c.670G>T p.G224* | Nonsense Mutation (SNP) | VAF 128/355 reads (36%) | catalogued as COSV57048018; called by muse, mutect2, varscan2
- FOXF2 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 142/572 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as rs377282345; called by muse, mutect2, varscan2
- FOXR2 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 195/545 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV59257863; called by muse, mutect2, varscan2
- FPR3 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 206/548 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as rs140768137; called by muse, mutect2, varscan2
- FREM1 | c.6028C>T p.P2010S | Missense Mutation (SNP) | VAF 165/215 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs934520223, COSV66530902; called by muse, mutect2, varscan2
- FREM1 | c.4007C>T p.S1336F | Missense Mutation (SNP) | VAF 108/294 reads (37%) | SIFT tolerated (0.61); PolyPhen benign (0.035); catalogued as rs774075087, COSV66525123; called by muse, mutect2, varscan2
- FREM1 | c.3601T>C p.F1201L | Missense Mutation (SNP) | VAF 248/339 reads (73%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV66532064; called by muse, mutect2, varscan2
- FREM2 | c.4582G>A p.D1528N | Missense Mutation (SNP) | VAF 157/395 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs200308898, COSV54850360; called by muse, mutect2, varscan2
- FREM3 | c.4534G>A p.E1512K | Missense Mutation (SNP) | VAF 135/402 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs748622688, COSV61678901; called by muse, mutect2, varscan2
- FRG2B | c.526G>A p.V176M | Missense Mutation (SNP) | VAF 173/638 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs753508884; called by muse, mutect2, varscan2
- FRMPD4 | c.3118C>T p.P1040S | Missense Mutation (SNP) | VAF 208/572 reads (36%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as COSV66222639; called by muse, mutect2, varscan2
- FRRS1 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 91/286 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs1264818092; called by muse, mutect2, varscan2
- FSHR | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 166/404 reads (41%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.577); catalogued as rs755098481, COSV58625878; called by muse, mutect2, varscan2
- FSIP2 | c.19007C>T p.S6336L | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.167); catalogued as COSV58078477; called by muse, mutect2, varscan2
- FSTL5 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 112/302 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.276); catalogued as rs1244772485; called by muse, mutect2, varscan2
- FUT3 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 166/566 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs1338525958, COSV54605934; called by muse, varscan2
- FUT7 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 263/624 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); catalogued as rs149025932; called by muse, mutect2, varscan2
- FYB2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 106/298 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs868676186, COSV58582820, COSV58583406; called by muse, mutect2, varscan2
- G6PC2 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 210/540 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99960978; called by muse, mutect2, varscan2
- GABRA3 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 214/563 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV64799165; called by muse, mutect2, varscan2
- GABRB3 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100160132, COSV54658447; called by muse, mutect2, varscan2
- GABRR3 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72084405; called by muse, mutect2, varscan2
- GAD1 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 111/293 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs1171048529; called by muse, mutect2, varscan2
- GAGE2A | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 131/434 reads (30%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.46); catalogued as COSV100760111, COSV62996050; called by muse, varscan2
- GALNT13 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.469); catalogued as COSV101222433, COSV67213201, COSV67235544; called by muse, mutect2, varscan2
- GALNT15 | c.1761G>A p.W587* | Nonsense Mutation (SNP) | VAF 90/260 reads (35%) | catalogued as rs1419613559; called by muse, mutect2, varscan2
- GANAB | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 106/292 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV60463202; called by muse, mutect2, varscan2
- GAP43 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 142/417 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV59344872; called by muse, varscan2
- GBP1 | c.1274G>A p.G425E | Missense Mutation (SNP) | VAF 198/547 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as rs779833354; called by muse, mutect2
- GCK | c.29C>T p.A10V | Missense Mutation (SNP) | VAF 130/476 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV67883940; called by muse, mutect2, varscan2
- GCNT1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 125/353 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65057480; called by muse, mutect2, varscan2
- GDA | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 91/273 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.48); catalogued as rs1290170854, COSV99428980; called by muse, mutect2, varscan2
- GDF10 | c.1243A>G p.K415E | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs781845811; called by muse, mutect2, varscan2
- GDF2 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 161/447 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs1555208728; called by muse, mutect2, varscan2
- GFRA1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 177/512 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.509); catalogued as rs777650834, COSV62603981, COSV62607405; called by muse, mutect2, varscan2
- GGT2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 49/210 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs1263422861; called by muse, varscan2
- GIPC3 | c.868C>T p.R290C (on ENST00000644946; = p.S285= on NM_133261.3) | Missense Mutation (SNP) | VAF 192/470 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs766192644, COSV59260175; called by muse, mutect2, varscan2
- GK2 | c.838G>A p.G280R | Missense Mutation (SNP) | VAF 124/389 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV62626867; called by muse, mutect2, varscan2
- GK2 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 153/402 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764161856; called by muse, mutect2, varscan2
- GLI2 | c.2254G>A p.E752K (on ENST00000361492 / NM_001374353.1; = p.E769K on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/322 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV58050210; called by muse, mutect2, varscan2
- GLP1R | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 85/310 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64714118, COSV64714630; called by muse, mutect2, varscan2
- GLRA4 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 133/346 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.152); catalogued as rs747630275; called by muse, mutect2, varscan2
- GLRB | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52415538; called by muse, mutect2, varscan2
- GLYATL3 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 99/267 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225939229, COSV64592784; called by muse, mutect2, varscan2
- GMFG | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 68/218 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as rs1383405600, COSV53418973; called by muse, mutect2, varscan2
- GML | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 137/368 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV55277086, COSV55277879; called by muse, mutect2, varscan2
- GNA14 | c.258G>A p.M86I | Missense Mutation (SNP) | VAF 155/430 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.414); catalogued as rs771132285; called by muse, mutect2, varscan2
- GNA15 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 164/431 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as rs1246435230; called by muse, mutect2, varscan2
- GNPAT | c.1654A>T p.T552S | Missense Mutation (SNP) | VAF 148/363 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs766788363; called by muse, mutect2, varscan2
- GNS | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1376910933; called by muse, mutect2, varscan2
- GOLGA6L22 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.23); catalogued as rs1320008493; called by muse, mutect2, varscan2
- GOLGA6L6 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 43/383 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV101417057; called by muse, mutect2, varscan2
- GP6 | c.374C>T p.S125L | Missense Mutation (SNP) | VAF 210/529 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1411106085, COSV59978511; called by muse, mutect2, varscan2
- GPATCH8 | c.4244C>T p.P1415L | Missense Mutation (SNP) | VAF 145/448 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100132423; called by muse, mutect2, varscan2
- GPC3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 141/450 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs1158430569; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPC5 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 126/335 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65588549; called by muse, mutect2, varscan2
- GPR101 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 189/563 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV53238418; called by muse, mutect2, varscan2
- GPR137 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 182/495 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs1474705240; called by muse, mutect2, varscan2
- GPR142 | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 172/627 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs149095547; called by muse, mutect2, varscan2
- GPR151 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 180/398 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.159); catalogued as rs771908470, COSV57033573; called by muse, mutect2, varscan2
- GPR158 | c.1031G>A p.G344E | Missense Mutation (SNP) | VAF 83/271 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66269793; called by muse, mutect2, varscan2
- GPR33 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 167/464 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs767940921; called by muse, mutect2, varscan2
- GPR55 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 76/216 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs866261794, COSV67408861; called by muse, mutect2, varscan2
- GPR61 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 187/508 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100879806; called by muse, mutect2, varscan2
- GPX5 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 98/445 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as COSV69079238; called by muse, mutect2, varscan2
- GRB14 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 46/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55738409, COSV99814333; called by muse, mutect2, varscan2
- GRIA1 | c.2107G>A p.G703R | Missense Mutation (SNP) | VAF 135/376 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53625533; called by muse, mutect2, varscan2
- GRIA2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as rs138878122, COSV99644710; called by muse, mutect2, varscan2
- GRIA2 | c.1372G>A p.G458R | Missense Mutation (SNP) | VAF 156/429 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV52385291; called by muse, mutect2, varscan2
- GRIA2 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs267600059, COSV52381695, COSV99644046; called by muse, mutect2, varscan2
- GRIK2 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 124/193 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs1269034550, COSV59752057; called by muse, mutect2, varscan2
- GRIK4 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 107/167 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs1234274683, COSV70804710; called by muse, mutect2, varscan2
- GRIK5 | c.1909G>A p.A637T | Missense Mutation (SNP) | VAF 112/340 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555872809, COSV99490929; called by muse, mutect2, varscan2
- GRIN2A | c.1959G>A p.M653I | Missense Mutation (SNP) | VAF 139/343 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV58021560; called by muse, mutect2, varscan2
- GRIN2A | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 151/429 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs148531310, COSV58023390; called by muse, mutect2, varscan2
- GRIN2B | c.1459G>A p.G487R | Missense Mutation (SNP) | VAF 107/332 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV74207966; called by muse, mutect2, varscan2
- GRIN2C | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 215/378 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs775414837; called by muse, mutect2, varscan2
- GRM3 | c.1615T>A p.Y539N | Missense Mutation (SNP) | VAF 270/510 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV64468234; called by muse, varscan2
- GRM6 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 117/329 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.506); catalogued as COSV51439389, COSV99179911; called by muse, mutect2, varscan2
- GRM8 | c.2618G>A p.G873E | Missense Mutation (SNP) | VAF 309/576 reads (54%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.461); catalogued as COSV58807935; called by muse, mutect2, varscan2
- GRXCR2 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 134/322 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV65061592; called by muse, mutect2, varscan2
- GSDMC | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 81/229 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs753181335, COSV52693054; called by muse, mutect2, varscan2
- GTF3C5 | c.193C>T p.R65W | Missense Mutation (SNP) | VAF 119/366 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766526872, COSV59600161; called by muse, mutect2, varscan2
- GTPBP3 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 124/373 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs931123101; called by muse, mutect2, varscan2
- GYS1 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 117/368 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV54401720; called by muse, mutect2, varscan2
- H2BW1 | c.283G>A p.G95S | Missense Mutation (SNP) | VAF 173/460 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782371401; called by muse, mutect2, varscan2
- HAS1 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 120/370 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as rs1313761117; called by muse, mutect2, varscan2
- HBB | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 144/359 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as rs33932070, COSV100092912; ClinVar: other; called by muse, varscan2
- HBD | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 128/337 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV53082743; called by muse, mutect2, varscan2
- HCAR3 | c.177G>A p.W59* | Nonsense Mutation (SNP) | VAF 165/436 reads (38%) | catalogued as rs763845816; called by muse, mutect2, varscan2
- HCN3 | c.2293C>T p.P765S | Missense Mutation (SNP) | VAF 134/1149 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs754284796, COSV61361246; called by muse, mutect2, varscan2
- HCRTR2 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 106/314 reads (34%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs1473143718, COSV63796528; called by muse, mutect2, varscan2
- HDAC9 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 98/372 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV67776261; called by muse, mutect2, varscan2
- HDAC9 | c.2921G>A p.G974E | Missense Mutation (SNP) | VAF 189/342 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs1485280896, COSV67769001; called by muse, mutect2, varscan2
- HDC | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 118/353 reads (33%) | catalogued as rs1350902290, COSV51080705, COSV99075830; called by muse, mutect2, varscan2
- HDGFL1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 182/702 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as rs1455666814; called by muse, varscan2
- HDHD2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs200669234; called by muse, mutect2, varscan2
- HECW2 | c.4129G>A p.E1377K | Missense Mutation (SNP) | VAF 77/217 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53648466, COSV53662828; called by muse, mutect2, varscan2
- HECW2 | c.1018G>A p.G340R | Missense Mutation (SNP) | VAF 182/489 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99648431; called by muse, mutect2, varscan2
- HEPHL1 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 103/148 reads (70%) | catalogued as rs374346546; called by muse, mutect2, varscan2
- HHIP | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 130/324 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56842508; called by muse, mutect2, varscan2
- HKDC1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs747283338, COSV63575537; called by muse, mutect2, varscan2
- HMCN1 | c.9730C>T p.P3244S | Missense Mutation (SNP) | VAF 156/223 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs141255890; called by muse, mutect2, varscan2
- HNF1A | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 117/343 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.191); catalogued as rs747416693, CD132723, CM082864, COSV57464468; called by muse, mutect2, varscan2
- HNRNPH2 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 174/432 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV99516245; called by muse, mutect2, varscan2
- HOXA11 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 218/471 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV50054426; called by mutect2, varscan2
- HROB | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 138/386 reads (36%) | catalogued as rs1567714946, COSV55368782; called by muse, mutect2, varscan2
- HSF4 | c.1022C>T p.P341L (on ENST00000521374 / NM_001040667.3; = p.P311L on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/435 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1206776401; called by muse, mutect2, varscan2
- HSPA1B | c.1850C>T p.P617L | Missense Mutation (SNP) | VAF 232/686 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.011); catalogued as rs867170652, COSV65128275; called by muse, mutect2, varscan2
- HSPA4 | c.569C>T p.A190V | Missense Mutation (SNP) | VAF 126/297 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs375495698; called by muse, mutect2, varscan2
- HTR3A | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 79/139 reads (57%) | catalogued as rs1038130014; called by muse, mutect2, varscan2
- HTRA1 | c.1297G>A p.V433I | Missense Mutation (SNP) | VAF 84/249 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.13); catalogued as rs751200867, COSV64563953; called by muse, mutect2, varscan2
- HUWE1 | c.10969C>G p.Q3657E | Missense Mutation (SNP) | VAF 133/370 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs1556921657; called by muse, mutect2, varscan2
- HUWE1 | c.9131G>A p.R3044Q | Missense Mutation (SNP) | VAF 157/420 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as rs1556928475; called by muse, mutect2, varscan2
- HUWE1 | c.8477C>T p.S2826F | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as COSV53339214; called by muse, mutect2, varscan2
- HYAL4 | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 202/414 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56138870, COSV56140506; called by muse, mutect2, varscan2
- HYDIN | c.13718C>T p.S4573F | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs768122625; called by muse, mutect2, varscan2
- HYDIN | c.11630G>A p.S3877N | Missense Mutation (SNP) | VAF 166/417 reads (40%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as rs1161156870; called by muse, mutect2, varscan2
- HYDIN | c.7639G>A p.D2547N | Missense Mutation (SNP) | VAF 204/509 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.131); catalogued as rs757454825; called by muse, mutect2, varscan2
- HYDIN | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 86/496 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.613); catalogued as rs377083406; called by muse, varscan2
- IARS1 | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 65/197 reads (33%) | catalogued as rs373980273; called by muse, mutect2, varscan2
- IDS | c.1006+1G>A p.X336_splice | Splice Site (SNP) | VAF 100/281 reads (36%) | catalogued as CX931238; called by muse, mutect2, varscan2
- IGFL4 | c.207G>C p.W69C | Missense Mutation (SNP) | VAF 196/511 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV66618830; called by muse, mutect2
- IGHE | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 167/489 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.03); catalogued as rs781850078; called by muse, mutect2, varscan2
- IGHM | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 168/371 reads (45%) | SIFT tolerated (0.13); catalogued as rs558134716; called by muse, mutect2, varscan2
- IGHM | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 81/243 reads (33%) | SIFT tolerated (0.05); catalogued as rs1228462995; called by muse, mutect2, varscan2
- IGHV1-24 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 112/303 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.455); catalogued as rs782009554; called by muse, mutect2, varscan2
- IGHV1-46 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 128/384 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1555524836; called by muse, mutect2, varscan2
- IGHV6-1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 112/316 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1555405707; called by muse, mutect2, varscan2
- IGKV1-12 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 177/999 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.529); catalogued as rs756917644; called by muse, mutect2, varscan2
- IGKV1-8 | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 104/296 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs1192735888; called by muse, varscan2
- IGKV3D-7 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 71/406 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as rs1467183490; called by muse, varscan2
- IGLV2-8 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 399/532 reads (75%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.019); catalogued as rs1401044535; called by muse, mutect2, varscan2
- IGSF5 | c.957G>A p.K319= | Splice Region (SNP) | VAF 76/192 reads (40%) | catalogued as COSV66030182; called by muse, mutect2, varscan2
- IKZF1 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 133/255 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58789252; called by muse, mutect2, varscan2
- IL20RB | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT tolerated (0.53); PolyPhen benign (0.059); catalogued as rs1205251540; called by muse, varscan2
- IMPA2 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 79/213 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as rs1218047852, COSV52321099; called by muse, mutect2, varscan2
- INO80D | c.2240C>T p.P747L | Missense Mutation (SNP) | VAF 115/394 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.24); catalogued as rs1426131528; called by muse, mutect2, varscan2
- INPP4B | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 87/281 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.572); catalogued as COSV99526037; called by muse, mutect2, varscan2
- INPP5D | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 132/320 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs762326413; called by muse, mutect2
- INTS12 | c.851C>T p.S284L | Missense Mutation (SNP) | VAF 98/287 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.713); catalogued as rs769807375, COSV100415809; called by muse, mutect2, varscan2
- INTS6L | c.1007C>T p.S336L | Missense Mutation (SNP) | VAF 103/325 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV66083980; called by muse, varscan2
- IQCN | c.1777C>T p.P593S | Missense Mutation (SNP) | VAF 170/457 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs1039053122; called by muse, mutect2, varscan2
- IQSEC2 | c.3548C>T p.P1183L | Missense Mutation (SNP) | VAF 150/324 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs1302692296; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IQUB | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 144/285 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100227462, COSV61238675; called by muse, mutect2, varscan2
- IRX4 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 163/467 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546936608, COSV99180842; called by muse, mutect2, varscan2
- ISX | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 219/298 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372031013; called by muse, mutect2, varscan2
- ITGA8 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 122/336 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.309); catalogued as COSV65233238; called by muse, mutect2, varscan2
- ITGA8 | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 151/416 reads (36%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.461); catalogued as COSV65223985; called by muse, mutect2, varscan2
- ITGAD | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 115/322 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1369419074, COSV66756591; called by muse, mutect2, varscan2
- ITGAD | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 113/341 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV66757464; called by muse, mutect2, varscan2
- ITGAL | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV63323757; called by muse, mutect2, varscan2
- ITGB2 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 133/339 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375038257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGB4 | c.3112-1G>A p.X1038_splice | Splice Site (SNP) | VAF 180/340 reads (53%) | catalogued as rs1241150781, CS064421, COSV99565045; called by muse, mutect2, varscan2
- ITGB6 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs188076755, COSV104393009; called by muse, mutect2, varscan2
- ITIH5 | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 155/477 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.162); catalogued as COSV53673545; called by muse, mutect2
- ITIH6 | c.1720G>A p.D574N | Missense Mutation (SNP) | VAF 200/574 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV54495472; called by muse, mutect2, varscan2
- ITLN1 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 90/594 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100406260; called by muse, mutect2, varscan2
- ITPR1 | c.1061C>T p.S354F (on ENST00000354582; = p.S339F on NM_002222.7) | Missense Mutation (SNP) | VAF 135/362 reads (37%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.474); catalogued as COSV56974623; called by muse, mutect2, varscan2
- ITPR1 | c.4052C>T p.S1351F (on ENST00000354582; = p.S1336F on NM_002222.7) | Missense Mutation (SNP) | VAF 131/363 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56979752; called by muse, mutect2, varscan2
- ITPR2 | c.4481C>T p.P1494L | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as COSV101189797; called by muse, mutect2, varscan2
- ITPR3 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 89/421 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs753753894, COSV65412158; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1162C>T p.R388C | Missense Mutation (SNP) | VAF 169/437 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1364216861; called by muse, mutect2, varscan2
- JCAD | c.2593G>A p.E865K | Missense Mutation (SNP) | VAF 193/499 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.077); catalogued as COSV64757680; called by muse, mutect2, varscan2
- JPH1 | c.1418G>T p.S473I | Missense Mutation (SNP) | VAF 173/452 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.229); catalogued as rs865986834; called by muse, mutect2, varscan2
- KBTBD3 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 95/172 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs369236490; called by muse, mutect2, varscan2
- KCMF1 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 177/457 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs979896332, COSV69053863; called by muse, mutect2, varscan2
- KCNA3 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 148/391 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV63902245; called by muse, mutect2, varscan2
- KCNC2 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 116/344 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100128562; called by muse, mutect2, varscan2
- KCND3 | c.1441C>T p.H481Y | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.904); catalogued as rs774941907; called by muse, mutect2, varscan2
- KCND3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 129/343 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100137521; called by muse, mutect2, varscan2
- KCNH5 | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 136/354 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as rs753034623; called by muse, mutect2, varscan2
- KCNH5 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 103/335 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604016, COSV59767610; called by muse, mutect2, varscan2
- KCNH7 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 125/298 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59800205; called by muse, mutect2, varscan2
- KCNH8 | c.2348C>T p.P783L | Missense Mutation (SNP) | VAF 130/429 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60466684, COSV60467691; called by muse, mutect2, varscan2
- KCNJ16 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 343/638 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1264510458; called by muse, mutect2, varscan2
- KCNK5 | c.1400C>T p.S467F | Missense Mutation (SNP) | VAF 163/629 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); catalogued as rs1380922096, COSV63989436; called by muse, mutect2, varscan2
- KCNS3 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 133/402 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868657815, COSV58408348; called by muse, mutect2, varscan2
- KCP | c.2374C>T p.L792F (on ENST00000620378; = p.L852F on NM_001366122.1) | Missense Mutation (SNP) | VAF 274/522 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.011); catalogued as rs1010603047; called by muse, varscan2
- KDELR2 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 278/499 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249951187; called by muse, mutect2, varscan2
- KDM2B | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 123/357 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV65637968; called by muse, mutect2, varscan2
- KIAA1217 | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 163/523 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56816776; called by muse, mutect2, varscan2
- KIAA1958 | c.1568C>T p.S523L | Missense Mutation (SNP) | VAF 202/517 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as rs370233153; called by muse, mutect2, varscan2
- KIF13A | c.3698C>G p.S1233W | Missense Mutation (SNP) | VAF 238/439 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52458501; called by muse, mutect2, varscan2
- KIF4B | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 122/353 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV70531367; called by muse, mutect2, varscan2
- KIR2DL1 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 175/722 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs944261925; called by muse, mutect2
- KIR2DL3 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 80/438 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1325006558; called by muse, mutect2
- KIR3DL1 | c.389C>T p.P130L | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV100428378; called by muse, mutect2, varscan2
- KL | c.2399C>T p.T800I | Missense Mutation (SNP) | VAF 114/326 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs1013502939, COSV101199209; called by muse, mutect2, varscan2
- KLC4 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 128/347 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs530185395, COSV52435471; called by muse, mutect2, varscan2
- KLHL13 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 159/431 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.061); catalogued as COSV53247842; called by muse, mutect2, varscan2
- KLHL13 | c.129G>A p.M43I | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV53247863; called by muse, mutect2, varscan2
- KLHL30 | c.1262G>A p.R421Q | Missense Mutation (SNP) | VAF 184/515 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs769587093, COSV59978725; called by muse, mutect2, varscan2
- KLHL40 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 98/259 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as rs372145157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL41 | c.844G>T p.V282F | Missense Mutation (SNP) | VAF 156/452 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.137); catalogued as COSV52931083; called by muse, mutect2
- KLKB1 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 138/347 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as COSV52993878; called by muse, mutect2, varscan2
- KMT2A | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 167/283 reads (59%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.005); catalogued as rs782112520, COSV63282976; called by muse, varscan2
- KMT2C | c.12122C>T p.P4041L | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1261796800, COSV51433883; called by muse, mutect2, varscan2
- KMT2D | c.9941C>T p.S3314F | Missense Mutation (SNP) | VAF 171/481 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs1258642596, COSV56407832; called by muse, mutect2, varscan2
- KMT2D | c.3422C>T p.P1141L | Missense Mutation (SNP) | VAF 192/474 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs767735696; called by muse, mutect2, varscan2
- KNDC1 | c.2782G>A p.D928N | Missense Mutation (SNP) | VAF 120/312 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV58836319; called by muse, mutect2, varscan2
- KNDC1 | c.3973G>A p.A1325T | Missense Mutation (SNP) | VAF 175/521 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as COSV58844629; called by muse, mutect2, varscan2
- KNL1 | c.5198C>T p.P1733L (on ENST00000346991 / NM_170589.5; = p.P1707L on NM_144508.5) | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV100705864; called by muse, mutect2, varscan2
- KRT20 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 137/399 reads (34%) | catalogued as COSV99071868; called by muse, mutect2, varscan2
- KRT23 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 109/339 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.1); catalogued as rs1237958319; called by muse, mutect2, varscan2
- KRT28 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 102/273 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100137650; called by muse, mutect2, varscan2
- KRT39 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 127/320 reads (40%) | catalogued as COSV62916783; called by muse, mutect2, varscan2
- KRT76 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 166/440 reads (38%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as COSV60120325; called by muse, varscan2
- KRT79 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 109/329 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs957307838, COSV57942855; called by muse, mutect2, varscan2
- KRT82 | c.1481G>A p.S494N | Missense Mutation (SNP) | VAF 127/367 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs773464151; called by muse, mutect2, varscan2
- KRT86 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 117/432 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs754512829; called by muse, mutect2, varscan2
- KRT86 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53292585; called by muse, mutect2, varscan2
- KRTAP26-1 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 165/402 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62128504; called by muse, mutect2, varscan2
- KRTAP3-1 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 194/495 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as rs774773070; called by muse, mutect2, varscan2
- KTN1 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.853); catalogued as rs1424108407; called by muse, mutect2, varscan2
- L1CAM | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 140/427 reads (33%) | catalogued as rs1557093439; called by muse, mutect2, varscan2
- L3MBTL4 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201734535, COSV99528338; called by muse, mutect2, varscan2
- L3MBTL4 | c.489G>A p.M163I | Missense Mutation (SNP) | VAF 97/230 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs868305340; called by muse, mutect2, varscan2
- LARGE2 | c.369G>A p.R123= | Splice Region (SNP) | VAF 90/248 reads (36%) | catalogued as COSV57684298; called by muse, mutect2, varscan2
- LARS1 | c.3223C>T p.Q1075* (on ENST00000394434 / NM_020117.11; = p.Q1048* on NM_016460.3) | Nonsense Mutation (SNP) | VAF 117/348 reads (34%) | catalogued as rs759414719; called by muse, mutect2, varscan2
- LATS2 | c.650C>T p.P217L | Missense Mutation (SNP) | VAF 165/453 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV66873383; called by muse, mutect2, varscan2
- LCE3A | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 163/943 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.011); catalogued as COSV59550516; called by muse, mutect2, varscan2
- LCT | c.5114G>A p.G1705E | Missense Mutation (SNP) | VAF 99/267 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as COSV51558559; called by muse, mutect2, varscan2
- LCT | c.2626G>A p.V876M | Missense Mutation (SNP) | VAF 136/386 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51555378; called by muse, mutect2, varscan2
- LDOC1 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 207/543 reads (38%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.519); catalogued as COSV100983222; called by muse, mutect2, varscan2
- LEMD3 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 186/528 reads (35%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.011); catalogued as rs1486752506; called by muse, mutect2, varscan2
4,366 further variants in this file (2,492 protein-altering or splice-affecting, 1,682 silent, 192 other) are not listed here.
